Somatic mutation profile of tumor specimen 0DJILQ from CCDI case PBBWYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.4 years (886 days).
Specimen 0DJILQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08eda2af-6fe1-435a-b248-d9eb2dfc27f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJIKT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e347cf58-f78f-4840-b7e0-5209a7a97286

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 53/632 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs769882996, COSV59873192; called by muse, mutect2
- ILDR2 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs777648089; called by muse, mutect2
- CSMD3 | c.9141T>A p.H3047Q (on ENST00000297405 / NM_001363185.1; = p.H2878Q on NM_052900.3) | Missense Mutation (SNP) | VAF 309/863 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LHX8 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 256/600 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by mutect2, varscan2
- MAGEC3 | c.396C>T p.N132= | Silent (SNP) | VAF 254/662 reads (38%) | catalogued as rs769899813, COSV100026263, COSV100026360; called by muse, mutect2
